CGCI case BLGSP-71-26-00398 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/38d9270c-89c2-4559-b48a-01aec87262c7

Demographics
Sex at birth: male; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 48.7 years (17,805 days); Year of diagnosis: 2015; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,022 days (2.8 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Axillary lymph nodes; Sites of involvement: Bone, NOS / Soft tissue / Liver / Pancreas, NOS.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Lymph nodes tested: 1; Tumor largest dimension diameter: 3 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 943 days (2.6 years); Disease response: Tumor Free.
- Days to follow up: 1,022 days (2.8 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day 305, day 319.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CCNE1 (IHC): Negative.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD34 (IHC): Negative.
- CD5 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 732 [Blood test normal range upper: 220].

Other clinical attributes
- Day 0: Comorbidities: Chlamydia.
- Day 0: Risk factors: Chlamydia.
- Day 0: Weight: 83 kg; Height: 181 cm; BMI: 25.3; Haart treatment indicator: Yes.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-26-00398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-26-00398-01-HE: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-26-00398-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-26-00398-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; History immunosuppresive diagnosis other: Chlamydia.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 4; Days from index date to tumor sample procurement: 1; Lymph nodes examined: Yes; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone; Extranodal involvement site: Soft Tissue (muscle, ligaments, subcutaneous); Extranodal involvement site: Liver; Extranodal involvement site: Pancreas.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 732; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: CD34.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: cycline.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
